Somatic mutation profile of tumor specimen TCGA-D5-6532-01A (aliquot TCGA-D5-6532-01A-11D-1719-10) from TCGA case TCGA-D5-6532, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-D5-6532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4296a4fe-5228-4cf2-adf4-d7d8c1e07c99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6532-10A (Blood Derived Normal), aliquot TCGA-D5-6532-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed282103-d45a-4aaa-8323-f14318fb9115

The open-access MAF lists 128 somatic variants for this specimen: 86 protein-altering or splice-affecting, 41 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 41, Nonsense Mutation 7, Frame Shift Del 4, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3956del p.P1319Lfs*2 | Frame Shift Del (DEL) | VAF 75/243 reads (31%) | catalogued as rs1057517558, COSV57356047, COSV57400437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FMO3 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs72549323, CM980769, CM990602, COSV63007948; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/69 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 224/568 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 72/152 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- VPS33B | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as rs121434384, CM041098, COSV60981001; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs746588103, COSV100068639; called by muse, mutect2, varscan2
- ABCA9 | c.2404A>C p.I802L | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60628335; called by muse, mutect2, varscan2
- ABLIM3 | c.1667A>T p.H556L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs1373461823, COSV58646273; called by muse, mutect2, varscan2
- ACAA1 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV57177314; called by muse, mutect2, varscan2
- ACTL9 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs782182119, COSV61006158; called by muse, mutect2, varscan2
- AMPD3 | c.362C>T p.T121M (on ENST00000396553 / NM_001025389.2; = p.T130M on NM_000480.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780348844, COSV67330561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100434629; called by muse, mutect2, varscan2
- APBA2 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67105258; called by muse, mutect2, varscan2
- ARFIP1 | c.452C>T p.S151L (on ENST00000353617 / NM_001287432.1; = p.S119L on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61885545; called by muse, mutect2, varscan2
- ARHGAP27 | c.1312C>T p.R438* (on ENST00000428638 / NM_001282290.1; = p.R97* on NM_199282.3) | Nonsense Mutation (SNP) | VAF 30/129 reads (23%) | catalogued as rs777988076, COSV65356991; called by muse, mutect2, varscan2
- ASPSCR1 | c.375-1G>T p.X125_splice | Splice Site (SNP) | VAF 34/164 reads (21%) | catalogued as COSV60730238; called by muse, mutect2, varscan2
- ATP2A3 | c.2209G>C p.D737H | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59231560; called by muse, mutect2, varscan2
- BEND3 | c.1005C>A p.F335L | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.098); catalogued as COSV100944621; called by muse, mutect2
- BLOC1S2 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58397501; called by muse, mutect2, varscan2
- CACNA2D4 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 223/297 reads (75%) | catalogued as rs367691073, COSV54955219; called by muse, mutect2, varscan2
- CAPN6 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759834539, COSV60695723; called by muse, mutect2, varscan2
- CCDC39 | c.2020C>G p.L674V | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56489082; called by muse, mutect2, varscan2
- CDK14 | c.682C>A p.L228M (on ENST00000380050 / NM_001287135.2; = p.L210M on NM_012395.3) | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV56044185; called by muse, mutect2, varscan2
- CLSTN2 | c.1587G>T p.M529I | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV101515777; called by muse, mutect2, varscan2
- COL5A2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs757439328, COSV66411929; called by muse, mutect2, varscan2
- CXXC5 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV56796025; called by muse, mutect2
- CYP2C8 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 105/169 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs781321835, COSV64878031; called by muse, mutect2, varscan2
- DCLK1 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99711624; called by muse, mutect2, varscan2
- DDAH1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs770957315, COSV99394943; called by muse, mutect2
- DEFB4A | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 95/468 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.38); catalogued as COSV100156644; called by muse, mutect2, varscan2
- FBN1 | c.355T>G p.C119G | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57324458; called by muse, mutect2, varscan2
- FEZF2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV51863760; called by muse, mutect2, varscan2
- GOLGA6A | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1289445564, COSV99297097; called by mutect2, varscan2
- GRIN2A | c.1114T>C p.W372R | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58046536; called by muse, mutect2, varscan2
- HEATR1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV100857205; called by muse, mutect2, varscan2
- IGLL1 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.44); catalogued as rs761551186, COSV99968604; called by muse, mutect2, varscan2
- INPPL1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753557940, COSV53360469; called by muse, mutect2, varscan2
- ITGAD | c.2998C>G p.P1000A | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV54932355; called by muse, mutect2, varscan2
- KCNB1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.007); catalogued as rs779750227, COSV65566501, COSV65570216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDHC | c.503C>G p.A168G | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55005175; called by muse, mutect2
- LRFN5 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53246766; called by muse, mutect2, varscan2
- LRP1B | c.1204A>C p.K402Q | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV101257738; called by muse, mutect2, varscan2
- LRP2 | c.11286C>A p.S3762R | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788800; called by muse, mutect2, varscan2
- LRRK2 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 84/254 reads (33%) | catalogued as rs766809708, COSV54157381, COSV54161437; called by muse, mutect2, varscan2
- MARCO | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs765172623, COSV59052524, COSV59056488; called by muse, mutect2, varscan2
- MME | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1157455203, COSV64707508; called by muse, mutect2, varscan2
- MOV10L1 | c.3355G>T p.D1119Y | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV53175793; called by muse, mutect2, varscan2
- MUC16 | c.42532T>G p.F14178V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.961); catalogued as COSV66694742; called by muse, mutect2
- MYH15 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as rs1560344013, COSV56315316; called by muse, mutect2, varscan2
- MYO5A | c.2501A>T p.Y834F | Missense Mutation (SNP) | VAF 122/355 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as COSV62562607; called by muse, mutect2, varscan2
- MYRIP | c.2257C>T p.L753F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV56873911, COSV56876009; called by muse, mutect2, varscan2
- PCCB | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 96/153 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV52446754; called by muse, mutect2, varscan2
- PCDHA2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as COSV65368669; called by muse, mutect2, varscan2
- PCLO | c.4557T>G p.S1519R | Missense Mutation (SNP) | VAF 109/270 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61651097; called by muse, mutect2, varscan2
- PKD1L1 | c.5401G>A p.V1801I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.442); catalogued as rs375771037; called by muse, mutect2, varscan2
- POLR2H | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 104/326 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55602872; called by muse, mutect2, varscan2
- PXDNL | c.2834C>A p.A945E | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs1158594975, COSV62478104, COSV62493633; called by muse, mutect2, varscan2
- RFX7 | c.1998T>G p.S666R (on ENST00000559447 / NM_001368074.1; = p.S763R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs1198669905, COSV57966510; called by muse, mutect2, varscan2
- RIMS1 | c.4111C>T p.R1371C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs995769455, COSV53465041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCML2 | c.1493G>T p.R498L | Missense Mutation (SNP) | VAF 296/330 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52621821, COSV52623536; called by muse, mutect2, varscan2
- SFMBT2 | c.1807A>T p.K603* | Nonsense Mutation (SNP) | VAF 62/159 reads (39%) | catalogued as COSV62813409; called by muse, mutect2, varscan2
- SLITRK2 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 196/228 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV59427160, COSV59427299; called by muse, mutect2, varscan2
- SPAG17 | c.3720A>C p.Q1240H | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs747481141, COSV60463544; called by muse, mutect2, varscan2
- SPATA9 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as COSV57224701; called by muse, mutect2, varscan2
- TAPBPL | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs758936057, COSV56946763; called by muse, mutect2, varscan2
- TBX22 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64787086; called by muse, mutect2, varscan2
- TFAM | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.249); catalogued as COSV65876694; called by muse, mutect2, varscan2
- TMPRSS11A | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 200/518 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs748931509, COSV58359897; called by muse, mutect2, varscan2
- TYK2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV99314848; called by muse, mutect2
- TYW3 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 247/687 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100904894; called by muse, varscan2
- UBE3A | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 59/174 reads (34%) | catalogued as COSV51664748; called by muse, mutect2, varscan2
- UBR4 | c.15008C>T p.T5003I | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776842584, COSV100921036; called by muse, mutect2, varscan2
- UGGT2 | c.1260G>C p.M420I | Missense Mutation (SNP) | VAF 164/384 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV65077092; called by muse, mutect2, varscan2
- XRN1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457905274, COSV53815150; called by muse, mutect2, varscan2
- ZNF445 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750089011, COSV101253793; called by muse, mutect2, varscan2
- ZNF804B | c.1793G>A p.S598N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV60841395; called by muse, mutect2, varscan2
- ZNF91 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as rs867302339, COSV56088756; called by muse, mutect2, varscan2
- ZSCAN5A | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV54229121; called by muse, mutect2, varscan2
- KLHDC10 | c.747_754del p.N250Ifs*3 | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- LARP1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- OPN1MW | c.865T>A p.C289S | Missense Mutation (SNP) | VAF 1581/1781 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PHPT1 | c.176_177del p.K59Sfs*13 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel, varscan2
- SMARCC1 | c.823_824del p.I275Ffs*3 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | called by pindel, varscan2
- ARHGAP1 | c.1083C>T p.P361= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs773769674, COSV56320360; called by muse, mutect2, varscan2
- ARSF | c.1140C>T p.R380= | Silent (SNP) | VAF 117/138 reads (85%) | catalogued as rs138210846, COSV100839525; called by muse, mutect2, varscan2
- ASXL3 | c.2154G>A p.P718= | Silent (SNP) | VAF 81/134 reads (60%) | catalogued as rs370185733, COSV52471685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.858C>A p.L286= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs755020643, COSV60814041; called by muse, mutect2, varscan2
- CAMK2A | c.396G>A p.V132= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs748571681, COSV62246984; called by muse, mutect2, varscan2
- CCDC38 | c.99C>G p.L33= | Silent (SNP) | VAF 132/305 reads (43%) | catalogued as rs771067919, COSV60183993; called by muse, mutect2, varscan2
- CFAP206 | c.450C>T p.I150= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV51535546; called by muse, mutect2, varscan2
- CREB3L3 | c.1242G>A p.S414= | Silent (SNP) | VAF 73/189 reads (39%) | catalogued as rs1568286651, COSV50176175; called by muse, mutect2, varscan2
- CRMP1 | c.183C>T p.N61= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs752770907, COSV61481635; called by muse, mutect2, varscan2
- DGKA | c.1908C>T p.I636= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV59387465; called by muse, mutect2, varscan2
- DNER | c.822C>T p.L274= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs779156111, COSV59171040; called by muse, mutect2, varscan2
- DNTT | c.57G>A p.T19= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs777964414, COSV64523378; called by muse, mutect2, varscan2
- DONSON | c.1700G>A p.*567= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV51665064; called by muse, mutect2, varscan2
- EFCAB13 | c.1341G>T p.S447= | Silent (SNP) | VAF 66/262 reads (25%) | catalogued as COSV58950681; called by muse, mutect2, varscan2
- H2AC17 | c.162G>C p.A54= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as COSV100377621; called by muse, mutect2, varscan2
- HECW1 | c.1785G>A p.S595= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV67835639; called by muse, mutect2, varscan2
- KLHL13 | c.1723A>C p.R575= | Silent (SNP) | VAF 18/302 reads (6%) | catalogued as COSV99451754; called by muse, mutect2
- MAGI2 | c.234C>T p.T78= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV62681543; called by muse, mutect2, varscan2
- MYH15 | c.450C>T p.P150= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs368538929; called by muse, mutect2, varscan2
- OR5AP2 | c.885C>T p.I295= | Silent (SNP) | VAF 93/264 reads (35%) | catalogued as COSV57257977; called by muse, mutect2, varscan2
- OR5M8 | c.621T>G p.S207= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as rs753438160, COSV59116399; called by muse, mutect2, varscan2
- OR8B2 | c.546C>A p.L182= | Silent (SNP) | VAF 40/579 reads (7%) | catalogued as COSV100899419, COSV66664211; called by muse, mutect2
- PAPPA | c.2406T>C p.F802= | Silent (SNP) | VAF 94/217 reads (43%) | catalogued as rs750761618, COSV60280852, COSV60288155; called by muse, mutect2, varscan2
- PCDHA5 | c.387G>A p.P129= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as COSV65350156, COSV65352674; called by muse, mutect2, varscan2
- PCDHGB4 | c.234C>T p.S78= | Silent (SNP) | VAF 75/322 reads (23%) | catalogued as COSV99539657; called by muse, varscan2
- PCLO | c.14757C>T p.A4919= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as rs746086173, COSV61651090; called by muse, mutect2, varscan2
- PDGFRA | c.132C>A p.S44= | Silent (SNP) | VAF 31/422 reads (7%) | catalogued as COSV99956746; called by muse, mutect2
- PLCB1 | c.1908T>C p.N636= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as rs778595698, COSV62060159; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLD5 | c.1605C>T p.N535= (on ENST00000442594; = p.N473= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/250 reads (36%) | catalogued as rs373263370, COSV100138693; called by muse, mutect2, varscan2
- PLG | c.2283A>C p.G761= | Silent (SNP) | VAF 24/311 reads (8%) | catalogued as COSV100369263; called by muse, mutect2
- PRDM16 | c.1680C>T p.S560= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs565375368, COSV54599842; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRDM2 | c.2535A>G p.E845= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as rs1490595365, COSV52451338; called by muse, mutect2, varscan2
- PROKR1 | c.651C>T p.C217= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as rs1214541096, COSV58137888; called by muse, mutect2, varscan2
- SLC6A3 | c.1479C>T p.I493= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs764518683, COSV54366958; called by muse, mutect2, varscan2
- SLIT3 | c.396G>A p.T132= | Silent (SNP) | VAF 52/175 reads (30%) | catalogued as rs771277109, COSV60622988; called by muse, mutect2, varscan2
- SPHKAP | c.3606C>T p.I1202= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs1432859065, COSV60872422; called by muse, mutect2, varscan2
- SPP2 | c.105C>T p.Y35= | Silent (SNP) | VAF 75/221 reads (34%) | catalogued as rs753888543, COSV51446137; called by muse, mutect2, varscan2
- SUN5 | c.735C>T p.N245= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as rs750892936, COSV62181832, COSV62182343; called by muse, mutect2, varscan2
- TBC1D32 | c.1473C>T p.Y491= | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as COSV51548848; called by muse, mutect2, varscan2
- TGIF2LY | c.18C>T p.D6= | Silent (SNP) | VAF 301/330 reads (91%) | catalogued as COSV58291840; called by muse, mutect2, varscan2
- ZNF552 | c.633T>C p.H211= | Silent (SNP) | VAF 91/245 reads (37%) | catalogued as rs762774311, COSV66971821; called by muse, mutect2, varscan2
- UBTFL2 | n.482A>G | RNA (SNP) | VAF 51/261 reads (20%) | called by muse, mutect2, varscan2
